TCGA case TCGA-06-1805 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f004b8a-f202-419d-a4d8-01f9430eaca5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 28 years; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 28.9 years (10,542 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 74 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 74 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 35 days; Days to treatment end: 76 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 44 days; Number of cycles: 3; Treatment dose: 200 mg/m2; Treatment outcome: Treatment Ongoing; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 105 days; Days to treatment end: 433 days (1.2 years).

Follow-up (4 entries)
- Days to follow up: 128 days; Disease response: With Tumor.
- Days to follow up: 1,031 days (2.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 80; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-1805-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-06-1805-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-06-1805-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-06-1805-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-1805-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Temozolomode.
- Follow-up form 2: Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,031 days; disease-specific survival: no event (censored), 1,031 days; progression-free interval: no event (censored), 1,031 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-1805-01A-01D-0591-01): tumor purity 0.72, ploidy 1.95, whole-genome doublings 0.
